Surgical pathology report (de-identified scan), TCGA case TCGA-24-2289, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2289-01A (Primary Tumor).

[page 1 of 3]
FINAL WITH ADDENDUM

*** Converted Case * This report may not match the original report format**

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: [REDACTED]

DOB: [REDACTED]

Physician(s): [REDACTED]

Service: [REDACTED]

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Accession #:

Taken:

Received:

Accessioned: [REDACTED]

Reported: [REDACTED]

TCGA-24-2289

DIAGNOSIS:

OMENTUM, PARTIAL OMENTECTOMY (FS1)

- POORLY DIFFERENTIATED ADENOCARCINOMA CONSISTENT WITH PRIMARY PERITONEAL SEROUS ADENOCARCINOMA (SEE DESCRIPTION)

OMENTUM, EXCISION

- POORLY DIFFERENTIATED ADENOCARCINOMA CONSISTENT WITH PRIMARY PERITONEAL SEROUS ADENOCARCINOMA (SEE DESCRIPTION)

OVARY, RIGHT, BIOPSY (FS2)

- POORLY DIFFERENTIATED ADENOCARCINOMA, SURFACE INVOLVEMENT CONSISTENT WITH PRIMARY PERITONEAL SEROUS ADENOCARCINOMA (SEE DESCRIPTION)
- SEROUS CYSTADENOMA

SOFT TISSUE, SUBMITTED AS "LEFT OVARIAN BIOPSY", BIOPSY

- POORLY DIFFERENTIATED ADENOCARCINOMA

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By Conversion [REDACTED]

Intraoperative Consultation:

FS1: Omentum, partial omentectomy - Metastatic carcinoma, favor mullerian tract primary [REDACTED]

FS2: Ovary, right, biopsy - Adenocarcinoma [REDACTED]

Microscopic Description and Comment:

The omentum is largely replaced by poorly differentiated adenocarcinoma. The tumor grows predominantly in a solid nested pattern, although there are micropapilli and scattered psammoma bodies consistent with serous differentiation. Small foci of

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

histologically identical tumor are confined to the surface of the right ovary with only focal, minimal cortical involvement. The right ovary also contains a serous cystadenoma. The specimen submitted as "left ovarian biopsy" consist of fibromuscular tissue with small foci of adenocarcinoma. Ovarian tissue is not identified. The distribution of tumor in this case, predominantly extraovarian with only minimal, superficial ovarian involvement, is consistent with a primary peritoneal serous carcinoma assuming that the patient has no other primary source to explain the peritoneal disease. [REDACTED]

History:

The patient is a [REDACTED] with pleural effusion, omental caking, pelvic mass, rule out ovarian cancer. Operative procedure: Examination under anesthesia, exploratory laparotomy, omentectomy. [REDACTED]

Specimen(s) Received:

A: FS1-OMENTUM PARTIAL OMENTERTOMY
B: X1-OMENTUM PARTIAL OMENTERTOMY
C: FS2-OVARY RIGHT BIOPSY
D: X2-OVARY RIGHT BIOPSY
E: LEFT OVARIAN BIOPSY
F: OMENTUM

Gross Description:

The specimens are received in six containers of formalin, each labeled with the patient's name. The first container is labeled "FS1." It contains two fragments of tan, soft tissue measuring 2.1 x 1.4 x 0.2 cm in aggregate. [REDACTED]

The second container is labeled "FS2." It contains two fragments of tan, soft tissue measuring 2 x 1.3 x 0.2 cm in aggregate. [REDACTED]

The third container is labeled "X1, omentum." It contains a fragment of tan, multinodular, soft tissue measuring 7 x 5 x 2 cm. The specimen consists of tan-white, firm tumor admixed with very little fat. [REDACTED]

The fourth container is labeled "X2, right ovarian biopsy for frozen section." It contains two fragments of tan, soft tissue measuring 2 x 2 x 1.7 cm. A cyst measuring 1.7 cm in greatest dimension is identified. Multiple, nodular, solid growths are seen on the inner surface of the cyst, measuring 0.7 cm in greatest dimension. [REDACTED]

The fifth container is labeled "left ovary biopsy." It contains multiple fragments of tan, soft tissue measuring 0.9 x 0.7 x 0.4 cm in aggregate. [REDACTED]

The sixth container is labeled "omentum." It contains multiple fragments of tan, soft tissue measuring 11 x 11 x 5 cm in aggregate. The specimen consists of tan-white, solid, firm tumor admixed with fat. Labeled B1, B2. Jar 2. [REDACTED]

Addendum Comment

An immunohistochemical stain for Her2neu (c-erbB-2) was performed on a representative tissue section from block [REDACTED]

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

X1A, using a polyclonal antibody-based assay (HercepTest). No immunoreactivity for this oncoprotein was observed.

Interpretation: negative for c-erbB-2

Source: NCI Genomic Data Commons file 85d876a8-b300-4a3c-9c12-2ad922d63a49 (TCGA-24-2289.3C9BB67A-702F-4E9B-BD0F-C0EF8A5D237D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).